Somatic mutation profile of tumor specimen TCGA-QH-A6XA-01A (aliquot TCGA-QH-A6XA-01A-12D-A32B-08) from TCGA case TCGA-QH-A6XA, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 23.3 years (8,508 days).
Specimen TCGA-QH-A6XA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc15f099-0d68-437c-8a0d-f737db29e0b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6XA-10B (Blood Derived Normal), aliquot TCGA-QH-A6XA-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d028610-72ff-4d24-ba9b-f2b7b9de2aa2

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 17/22 reads (77%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C1QTNF1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as rs566478936, COSV59263416; called by muse, mutect2, varscan2
- NT5DC2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs573448959, COSV58732672; called by muse, mutect2, varscan2
- OBP2A | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs774820578, COSV59793363; called by muse, mutect2, varscan2
- POLB | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368102815, COSV55347077; called by muse, mutect2, varscan2
- TSPAN8 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs148575105; called by muse, mutect2, varscan2
- TTC37 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs753958286, COSV100706276; called by muse, mutect2, varscan2
- ATRX | c.2632_2634delinsCA p.D878Qfs*27 | Frame Shift Del (DEL) | VAF 89/403 reads (22%) | called by pindel, varscan2*
- IL22RA1 | c.1441C>T p.L481= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as rs771195444, COSV99582657; called by muse, mutect2, varscan2
- JPH2 | c.891C>T p.N297= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs796364747, COSV65905211; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPPL3 | c.369A>G p.R123= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100793533; called by muse, mutect2, varscan2
